Gene-level copy-number profile of specimen HCM-CSHL-0393-C18-85A from HCMI case HCM-CSHL-0393-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G4.
Specimen HCM-CSHL-0393-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c403825c-c02f-4dcb-b8e2-605183d3fead.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0393-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,741 have no estimate.
https://portal.gdc.cancer.gov/files/5db4a787-4c10-49ac-88e9-c8959051c81c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 10,075; copy number 2: 26,169; copy number 3: 15,877; copy number 4: 6,219; copy number 5: 170; copy number 6: 149; copy number 7: 98; copy number 8: 2; copy number 12: 1; copy number 13: 87.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–1): MIR31HG.
- chr9:21,480,839–23,956,444, 34 genes (within-gene range 0–1): IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 507 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,522,280–42,164,745, 83 genes, copy number 13 (within-gene range 4–13) (broad region; genes not listed).
- chr1:149,197,992–149,747,818, 15 genes, copy number 5 (within-gene range 4–5): AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P.
- chr1:188,869,474–190,801,658, 14 genes, copy number 5 (within-gene range 4–5): AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720.
- chr3:148,850,933–152,800,732, 92 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr4:52,252,820–56,033,361, 73 genes, copy number 5–6 (broad region; genes not listed).
- chr4:56,097,390–56,097,504, 1 gene, copy number 5 (within-gene range 4–5): RNA5SP161.
- chr7:115,503,367–115,833,373, 6 genes, copy number 6–7: POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA.
- chr9:61,190,003–61,662,690, 11 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr11:64,359,148–64,803,241, 16 genes, copy number 5–6: RPS6KA4, MIR1237, LINC02723, AP003774.1, LINC02724, AP005273.1, AP006288.1, SLC22A11, SLC22A12, NRXN2, NRXN2-AS1, RASGRP2, PYGM, SF1, AP001462.1, MAP4K2.
- chr11:65,261,920–65,959,963, 58 genes, copy number 6: POLA2, AP000944.5, AP000944.7, CDC42EP2, DPF2, TIGD3, AP000944.1, SLC25A45, FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1, LTBP3, AP001362.1, ZNRD2-AS1, ZNRD2, FAM89B, EHBP1L1, KCNK7, MAP3K11, PCNX3, MIR4690, SIPA1, MIR4489, RELA, RELA-DT, RN7SL309P, KAT5, RNASEH2C, KRT8P26, AP001266.2, AP5B1, OVOL1, OVOL1-AS1, AP001266.1, CFL1, SNX32, MUS81, EFEMP2, CTSW, FIBP, CCDC85B, FOSL1, C11orf68, DRAP1, TSGA10IP.
- chr12:20,014,780–21,657,798, 22 genes, copy number 5 (within-gene range 3–5): LINC02398, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2.
- chr12:42,615,221–42,717,120, 6 genes, copy number 5: LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450.
- chr12:43,560,784–43,661,101, 4 genes, copy number 5: AC090525.1, AC090525.2, AC090525.3, EEF1A1P17.
- chr14:70,425,812–70,557,478, 6 genes, copy number 5 (within-gene range 4–5): AL357153.2, ADAM21, ADAM20P1, RNU6-659P, ADAM20, AL357153.4.
- chr18:12,304,091–13,652,755, 35 genes, copy number 5–8 (within-gene range 4–8): RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3, PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1, LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4.
- chr18:13,514,520–13,726,663, 7 genes, copy number 5 (within-gene range 4–5): AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P.
- chr18:13,824,149–15,330,282, 53 genes, copy number 5: MC5R, MC2R, AP001086.1, AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005901.2, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr20:54,153,446–54,859,812, 5 genes, copy number 12–13: CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P.

Autosomal genes at a single copy (total copy number 1): 7,731. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
